Somatic mutation profile of tumor specimen TCGA-J4-A67Q-01A (aliquot TCGA-J4-A67Q-01A-21D-A30E-08) from TCGA case TCGA-J4-A67Q, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 77.9 years (28,447 days).
Specimen TCGA-J4-A67Q-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2f081766-da95-4f49-aa0c-cf4b61d83d09.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-J4-A67Q-10A (Blood Derived Normal), aliquot TCGA-J4-A67Q-10A-01D-A30H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/946cb703-36b8-4919-91d8-d9ab4ee2275c

The open-access MAF lists 19 somatic variants for this specimen: 13 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 12, Silent 6, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.3232C>G p.L1078V | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV53742973; called by muse, mutect2
- CIAO2B | c.144T>A p.D48E | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.498); catalogued as COSV57696831; called by muse, mutect2
- COL16A1 | c.4286C>T p.S1429F | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.548); catalogued as COSV54700611, COSV54705261; called by muse, mutect2, varscan2
- HELB | c.1138G>A p.V380I | Missense Mutation (SNP) | VAF 57/231 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.626); catalogued as rs1309153688, COSV56073725; called by muse, mutect2, varscan2
- HNRNPAB | c.733C>T p.R245C | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs762962350, COSV57424162; called by muse, mutect2
- HOXB13 | c.290T>C p.L97P | Missense Mutation (SNP) | VAF 23/162 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV51705945; called by muse, mutect2, varscan2
- KIF11 | c.3154G>C p.A1052P | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.602); catalogued as COSV53270567; called by muse, mutect2, varscan2
- MYORG | c.941G>C p.R314P | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.687); catalogued as COSV52627175, COSV99898892; called by muse, mutect2, varscan2
- ROR2 | c.2413A>G p.K805E | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.626); catalogued as COSV65218851; called by muse, mutect2
- SF3B5 | c.222G>C p.Q74H | Missense Mutation (SNP) | VAF 27/157 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.039); catalogued as COSV62451297; called by muse, mutect2, varscan2
- TIMELESS | c.1373A>T p.D458V | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV57514585; called by muse, mutect2
- TLE4 | c.2228C>T p.S743L | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54631699; called by muse, mutect2, varscan2
- KLHL9 | c.451_452del p.L151Gfs*2 | Frame Shift Del (DEL) | VAF 8/53 reads (15%) | called by mutect2, pindel, varscan2
- CRIP3 | c.294C>G p.P98= | Silent (SNP) | VAF 14/87 reads (16%) | catalogued as COSV51483818; called by muse, mutect2, varscan2
- MYOM2 | c.1089C>T p.V363= | Silent (SNP) | VAF 13/54 reads (24%) | catalogued as COSV50711483; called by muse, mutect2, varscan2
- NFASC | c.2358C>T p.Y786= (on ENST00000339876 / NM_001378329.1; = p.Y782= on NM_015090.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as rs755968277, COSV58365131; called by muse, mutect2, varscan2
- OR4K2 | c.228C>T p.F76= | Silent (SNP) | VAF 53/382 reads (14%) | catalogued as rs370258306, COSV53848469; called by muse, mutect2, varscan2
- RAB11FIP3 | c.2229G>A p.V743= | Silent (SNP) | VAF 21/88 reads (24%) | catalogued as COSV51933293; called by muse, mutect2, varscan2
- TBL2 | c.279A>T p.I93= | Silent (SNP) | VAF 12/71 reads (17%) | catalogued as COSV59787024; called by muse, mutect2, varscan2
